Gene-level copy-number profile of tumor specimen C3N-01533-03 from CPTAC case C3N-01533, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.3 years (26,761 days).
Specimen C3N-01533-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cfbfdae7-c972-4a0f-ae8c-d17f7ec766b2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01533-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/ad3acd6f-3438-4e17-bd7f-914b806c7cb5

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 266; copy number 1: 1,671; copy number 2: 17,741; copy number 3: 22,134; copy number 4: 11,316; copy number 5: 4,539; copy number 6: 1,155; copy number 7: 51; copy number 9: 26.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–157,887, 13 genes (within-gene range 0–1): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.3, AL627309.7, AL627309.2, RNU6-1100P.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–3): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:21,802,636–22,029,594, 1 gene (within-gene range 0–3): AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes (within-gene range 0–3): AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:61,581,813–61,582,675, 1 gene: AL935212.3.
- chr14:73,537,143–73,543,796, 2 genes (within-gene range 0–3): ACOT1, NT5CP2.
- chr17:7,646,627–7,687,538, 2 genes (within-gene range 0–2): ATP1B2, TP53.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–2): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 77 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:67,878,316–67,986,503, 2 genes, copy number 7 (within-gene range 6–7): AL713998.1, AL713998.3.
- chr8:123,041,968–123,737,402, 28 genes, copy number 7 (within-gene range 4–7): TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13.
- chr10:35,896,874–36,089,389, 2 genes, copy number 7: LINC02630, AL355300.1.
- chr13:23,134,174–23,889,400, 15 genes, copy number 7 (within-gene range 3–7): HMGA1P6, RNY3P4, LINC00362, SGCG, RNU6-58P, TATDN2P3, SDAD1P4, SACS, RPLP1P13, SACS-AS1, LINC00327, LINC00352, TNFRSF19, MIPEP, MTCO3P2.
- chr16:24,537,693–24,827,632, 4 genes, copy number 7: RBBP6, TNRC6A, LINC01567, AC008731.1.
- chr20:47,501,887–49,046,168, 26 genes, copy number 9: NCOA3, AL034418.1, SULF2, AL354813.1, RNU7-173P, SRMP1, RNA5SP486, RNU7-92P, AL357558.2, AL357558.1, LINC01522, LINC01523, AL139351.1, AL121888.1, LINC00494, AL137078.1, AL137078.2, AL049541.1, AL049541.2, RNU7-144P, PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1.

Autosomal genes at a single copy (total copy number 1): 944. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
